Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GR, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GR-06A (Metastatic).

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

ICD-0-3

Melanoma, Nos 8720/3

Site: Subcutaneous, forearm
C49.1

ju 6/10/11

CLINICAL DETAILS

Local recurrence. See 3cm radial to exc scar.
4.4mm melanoma. (R forearm).

No wide excision thought stage IV at

There is a diagram indicating the site of the previous excision biopsy.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"LESION (RT FOREARM) SUTURE PROXIMAL". An oriented ellipse of skin 35 x 15 x 10mm in depth, orientated with a stitch at one tip marking proximal designated 12 o'clock. The 3 o'clock margin inked blue and the 9 o'clock margin inked black. There is a subcutaneous nodule up to 8mm across. The entire nodule embedded in one block (2 slices).

MICROSCOPIC REPORT

"LESION (RT FOREARM) SUTURE PROXIMAL".

The specimen consists of skin including subcutis. Microscopy shows nodular deposits of malignant tumour mainly within the subcutis with an occasional nodule in the deep reticular dermis. The tumour is composed of nests of epithelioid cells with one or more prominent nucleoli and moderate amount of eosinophilic cytoplasm. The nodules are scattered throughout the subcutis and some appear to be within lymphatics. No junctional or intraepidermal component is seen. The appearance is entirely consistent with recurrent melanoma.

Small islands of tumour extend to within 0.4mm of the deep margin. The closest peripheral margin is clear by approximately 2.7mm at the level of subcutis (3 o'clock).

SUMMARY

SKIN EXCISION, RIGHT FOREARM: MELANOMA, consistent with local recurrence.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 6f5556b8-27e2-4528-8b66-5e95632f58be (TCGA-EE-A2GR.845FD905-B92B-4D98-95A0-3E24164CC1A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).